Surgical pathology report (de-identified scan), TCGA case TCGA-BA-6872, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-6872-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

Diagnosis:

A: "Right alveolar ridge at [REDACTED]", biopsy.

- Ulcerated squamous mucosa [REDACTED]ked acute inflammation and reactive epithelial atypia.

B: "Mid lingual nerve", biopsy.

- Benign nerve with no tumor seen.

C: Tongue, right anterior, biopsy.

- No tumor seen.

D: Tongue, right mid mucosa, biopsy.

- No tumor seen.

E: Tongue, posterior mucosa, biopsy.

- No tumor seen.

F: Tongue, left deep margin, biopsy.

- No tumor seen.

G: Tongue, right deep margin, biopsy.

- No tumor seen.

H: Tongue, left posterior, biopsy.

- No tumor seen.

I: Tongue, left mid mucosa, biopsy.

- No tumor seen.

J: Tongue, left mid mucosa, biopsy.

- No tumor seen.

K: Tongue, left anterior, biopsy.

- No tumor seen.

L: Lymph node, right neck, level 1, excision.

- No tumor seen in three lymph nodes (0/3).

- Benign salivary gland with no tumor seen.

M: Lymph node, right neck, level 2, excision.

- No tumor seen in eight lymph nodes (0/8).

N: Lymph node, right neck, level 3, excision.

[page 2 of 8]
- Metastatic carcinoma present in 3 of 8 lymph nodes (3/8).
- Size of largest metastasis = 1.2cm

O: Lymph node, right neck, level 4, excision.

- No tumor seen in four lymph nodes (0/4).

P: Lymph node, right neck, level 5, excision.

- No tumor seen in three lymph nodes (0/3).

Q: Lymph node, right submental, excision.

- Metastatic carcinoma in 2 of 2 lymph nodes (2/2).
- Size of largest metastasis = 1.1 cm.

R: Lymph node, left neck, level 1, excision.

- Metastatic carcinoma in 1 of 11 lymph nodes (1/11).
- Size of metastasis = 1.0 cm.
- Salivary gland tissue with no tumor seen.

S: Lymph node, left neck, level 2, excision.

- No tumor seen in six lymph nodes (0/6).

T: Lymph node, left neck, level 3, excision.

- No tumor seen in five lymph nodes (0/5).

U: Marginal mandible and floor of mouth, mandibulectomy.

- Invasive moderately differentiated squamous cell carcinoma with invasion into floor of mouth deep muscle.
- Tumor size = 3.3 cm.
- Carcinoma extends to the posterior floor of mouth cauterized/inked surgical margin (U3).
- Mandibular bone including medial and lateral bony margins negative for carcinoma.

V: Floor of mouth, additional margin, excision.

- Benign salivary gland with no tumor seen.

W: Tooth, mandible, excision.

- Tooth present for gross examination only.

Comment:

None.

Intraoperative Consult Diagnosis:

[page 3 of 8]
FSA1: "Right areolar ridge at tooth 29", biopsy
- Ulcerated squamous mucosa with acute inflammation and granulation tissue, no carcinoma identified

FSB1: Mid lingual nerve, biopsy
- Fibrovascular connective tissue with nerve, no tumor identified

FSC1: Tongue, right anterior, biopsy
- No tumor seen

FSD1: Tongue, right mid tongue mucosa, biopsy
- No tumor seen

FSE1: Tongue, posterior mucosa, biopsy
- No tumor seen

FSF1: Tongue, left deep margin, biopsy
- No tumor seen

FSG1: Tongue, right deep margin, biopsy
- No tumor seen

FSH1: Tongue, left posterior, biopsy
- No tumor seen

FSI1: Tongue, left mid tongue mucosa, biopsy
- No tumor seen

FSJ1: Tongue, left mid tongue mucosa, biopsy
- No tumor seen

FSK1: Tongue, left anterior, biopsy
- No tumor seen

Clinical History:

The patient is a [REDACTED] with squamous cell carcinoma involving the mouth who undergoes bilateral modified radical neck dissection and excision of the tumor.

Gross Description:

Received are 23 appropriately labeled containers.

Specimen A is a 0.6 x 0.2 x 0.2 cm red/tan soft tissue

[page 4 of 8]
fragment, which is submitted as Block FSA1 [REDACTED]

Specimen B is a 0.3 x 0.2 x 0.1 cm red/tan soft tissue fragment, which is totally submitted as Block FSB1, [REDACTED]

Specimen C is a 0.4 x 0.2 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSC1, [REDACTED]

Specimen D is a 0.4 x 0.3 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSD1, [REDACTED]

Specimen E is a 0.3 x 0.3 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSE1, [REDACTED]

Specimen F is a 1.0 x 0.6 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSF1, [REDACTED]

Specimen G is a 0.7 x 0.2 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSG1, [REDACTED]

Specimen H is a 0.3 x 0.3 x 0.3 cm red/tan soft tissue fragment, which is totally submitted as Block FSH1, [REDACTED]

Specimen I is a 0.5 x 0.3 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSI1, [REDACTED]

Specimen J is a 0.5 x 0.4 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSJ1, [REDACTED]

Specimen K is a 0.5 x 0.3 x 0.2 cm red/tan soft tissue fragment, which is totally submitted as Block FSK1, [REDACTED]

Specimen L is identified as level 1 lymph node from the right neck. The specimen is a 6.0 x 4.0 x 2.0 cm red/yellow fibroadipose mass. The section reveals 3 lymph nodes, the largest measuring 1.5 cm. Each lymph node has a smooth red cut surface. Also identified is a large glandular structure measuring 3.0 x 3.5 x 2.5 cm. The glands cut surface is tan, smooth and lobulated without a lesion.

Block Summary:

- L1 - Three representative sections, largest lymph node
- L2 - Single lymph node, bisected
- L3 - Single lymph node, submitted whole and representative section of gland structure
- L4-5 - Additional representative sections of gland

[page 5 of 8]
structure

Specimen M is identified as lymph nodes from the right neck at level 2. The specimen is a 5.0 x 5.0 x 1.5 cm mass of fibroadipose tissue and fragments of muscle. The section reveals 7 apparent lymph nodes, ranging in size from 2.3 cm to 0.4 cm. Each has a tan/red cut surface.

Block Summary:

M1 - Largest lymph node, bisected
M2 - 3 lymph nodes, submitted whole
M3 - 3 lymph nodes, submitted whole

Specimen N is identified as level 3 lymph nodes from the right neck. The specimen is a 6.5 x 4.5 x 2.8 cm mass of fibroadipose tissue and muscle. The section reveals 8 lymph nodes, ranging in size from 2.0 cm to 0.3 cm. Three of these lymph nodes are much firmer than usual with a white slightly milky cut surface. The remaining lymph nodes have a dark red smooth cut surface.

Block Summary:

N1 - Single white lymph node, bisected
N2 - Single white lymph node, bisected
N3 - Single white lymph node, bisected
N4 - Two lymph nodes, submitted whole
N5 - Three lymph nodes, submitted whole

Specimen O is identified as level 4 lymph nodes from the right neck. The specimen is a 5.0 x 3.6 x 1.0 cm mass of fibroadipose tissue. There are 5 lymph nodes present, each moderately firm with a smooth dark red cut surface. They range in size from 0.7 to 1.5 cm.

Block Summary:

O1 - Single lymph node, bisected
O2 - Single lymph node and smaller lymph node candidate, each submitted whole
O3 - Two lymph nodes submitted whole
O4 - One lymph node submitted whole

Specimen P is identified as level 5 lymph nodes from the right neck. The specimen is a long thin fibroadipose mass measuring 10.0 x 2.0 x 1.0 cm. A small amount of muscle is

[page 6 of 8]
also identified. Five lymph nodes and two lymph node candidates are found with the lymph nodes ranging in size from 0.5 to 1.0 cm. Each is firm and ovoid with a tan cut surface.

Block Summary:

P1 - Two lymph nodes, submitted whole
P2 - Three lymph nodes, submitted whole
P3 - Two lymph node candidates and surrounding adipose tissue, submitted whole

Specimen Q is identified as a right segmental lymph node. The specimen is a 1.4 x 1.2 x 0.6 cm white firm nodule with a rough external surface and soft whitish pink cut surface. This specimen is entirely submitted in Block Q1 NTR.

Specimen R is identified as level 1 lymph node from the left neck. The specimen is an irregularly shaped 7.0 x 4.5 x 2.0 cm mass of fibroadipose tissue. Within this specimen is a somewhat irregularly defined mass of glandular tissue measuring 3.1 x 3.5 x 1.5 cm. Its cut surface is light tan, smooth and lobulated without any mass lesions. Seven lymph nodes are identified ranging in size from 1.7 cm to 0.5 cm. The cut surface of one of the lymph nodes is white tan with focal white firm areas. The remainder of the lymph nodes has a dark red smooth cut surface.

Block Summary

R1 - Lymph node with adjacent smaller red lymph node, each bisected
R2 - Single lymph node bisected
R3 - Single lymph node bisected
R4 - Three lymph nodes, submitted whole
R5 - Two lymph nodes, submitted whole
R6-7 - Representative sections from glandular structure

Specimen S is identified as level 2 lymph nodes from the left neck. The specimen is a 4.5 x 3.0 x 1.0 cm fibroadipose mass. Four lymph nodes are identified ranging in size from 0.6 cm to 1.9 cm. Each has a smooth light tan cut surface.

Block Summary

S1 - Largest lymph node, bisected
S2 - 3 lymph nodes, submitted whole

[page 7 of 8]
Specimen T is identified as level 3 lymph nodes from the left neck. The specimen is a 4.9 x 3.5 x 1.0 cm fibroadipose mass. Three lymph nodes are identified ranging in size from 1.6 cm to 0.5 cm. Each is firm and pink.

Block Summary:

T1 - Three lymph nodes, submitted whole
T2 - Additional fibroadipose tissue

Specimen U is additionally labeled "marginal mandibulectomy and floor of mouth". The specimen is an en bloc resection consisting of a partial right mandible (3.5 x 1.6 x 1.1 cm), anterior floor of mouth (3.0 x 2.5 x 0.4 cm), and right sublingual gland (3.0 x 2.0 x 0.7 cm). The entire specimen measures 4.0 x 4.0 x 2.0 cm. The mandible has 7 intact teeth consisting of 4 incisors, one cuspid, and two premolars. The ventral surface has a large, raised, pink/tan discoid lesion that measures 3.3 x 2.5 x 0.2 cm and extends to involve the lower alveolar ridge mucosa. On cut section, the tumor surface is light tan and firm. The tumor is situated from the margin as follows: Anterior labial 0.6 cm, posterior floor of mouth border 0.1 cm, floor of mouth deep margin 0.2 cm, lateral soft tissue margin 0.3 cm, medial soft tissue margin 0.4 cm, lateral bone margin 1.0 cm, and medial bone margin 0.5 cm. The tumor does not grossly appear to involve the sublingual gland. Prior to sectioning, the specimen has been inked such that the anterior medial and lateral surfaces are blue. The posterior floor of mouth and deep floor of mouth margins black, and the sublingual gland yellow.

Block Summary:

U1 - Floor of mouth, medial margin, radial sections
U2 - Floor of mouth, lateral margin, radial sections
U3-U4 - Floor of mouth, posterior margin, perpendicular sections
U5 - Medial bone margin
U6 - Lateral bone margin
U7-U10 - Serial sections through the tumor demonstrating the anterior gingival and inferior bone margins
U11 - Sublingual gland

Specimen V is identified as the "additional margin from

[page 8 of 8]
floor of the mouth". The specimen is a 1.9 x 1.5 x 0.5 cm red/brown granular soft tissue fragment. The specimen is received with a long suture designating posterior and a short suture, designating superior. It is not indicated whether this specimen comes from the left or right side of the mouth. For inking purposes the specimen will be handled as if it was resected from the midline, with the posterior surface black, the anterior surface blue, the left lateral surface red and the right lateral surface yellow. Serial sectioning through the specimen reveals no mass lesions.

Block Summary:

- V1 - Posterior margin, cut perpendicular
- V2 - Anterior margin, cut perpendicular
- Serial sections through remainder of the specimen,

Specimen W is identified as "tooth mandible". The specimen is a 2.7 x 0.5 x 0.5 cm intact light tan hard tooth. No soft tissue is received with this specimen. This specimen is not submitted for light microscopic examination.

py:

Light microscopic examination is performed by Dr.

Source: NCI Genomic Data Commons file ee898ed7-ffe0-4bc1-8d12-38c3e86d69a8 (TCGA-BA-6872.B5ECD797-4FA4-48D5-9440-EAB667E86C7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).